Gene-level copy-number profile of tumor specimen BLGSP-71-06-00149-01B from CGCI case BLGSP-71-06-00149, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 13.1 years (4,775 days).
Specimen BLGSP-71-06-00149-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c55722fe-b0a3-47ac-970f-85c6971db723.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-06-00149-99A (granulocytes); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,255 have no estimate.
https://portal.gdc.cancer.gov/files/76abcf4e-26f4-474c-b2db-8ce33e4b9769

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 93; copy number 1: 217; copy number 2: 57,469; copy number 3: 544; copy number 4: 7; copy number 5: 10; copy number 6: 3; copy number 7: 10; copy number 9: 4; copy number 10: 2; copy number 11: 3; copy number 15: 1; copy number 26: 2; copy number 33: 1; copy number 74: 1; copy number 91: 1.

Homozygous deletions (total copy number 0; autosomes only): 93 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 3 genes (within-gene range 0–3): MALLP2, AC244205.1, MIR4436A.
- chr2:89,170,775–89,192,752, 4 genes (within-gene range 0–1): IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25.
- chr14:105,851,705–106,108,464, 49 genes (within-gene range 0–2): IGHM, MIR4539, MIR4507, MIR4538, MIR4537, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3, IGHV4-4, IGHV7-4-1, IGHV2-5, IGHVIII-5-1, IGHVIII-5-2, IGHV3-6, IGHV3-7, IGHV3-64D, IGHV5-10-1.
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–1): IGHVIII-16-1.
- chr15:21,328,380–21,951,323, 36 genes: AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 38 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,319,625–89,600,680, 3 genes, copy number 9: IGKV1-39, IGKV2-40, 5S_rRNA.
- chr5:70,495,100–70,500,903, 1 gene, copy number 6: AC146944.1.
- chr9:61,581,813–61,582,675, 1 gene, copy number 10: AL935212.3.
- chr9:64,878,790–65,285,209, 6 genes, copy number 5–74: AC125634.1, RNU6-1293P, BMS1P12, AL512605.1, AL512605.2, FOXD4L5.
- chr9:66,082,350–66,085,031, 2 genes, copy number 5: SNX18P4, AL513478.1.
- chr13:41,061,509–41,084,006, 1 gene, copy number 5: WBP4.
- chr15:20,890,206–21,058,440, 8 genes, copy number 5–91 (within-gene range 1–91): AC012414.5, AC037471.2, ZNF519P2, NF1P1, MIR5701-1, LINC01193, OR11J2P, OR11J5P.
- chr15:21,102,843–21,103,138, 1 gene, copy number 15: RN7SL400P.
- chr15:21,293,653–21,307,855, 2 genes, copy number 9–33: AC068446.1, RNU6-1235P.
- chr15:21,980,277–21,981,245, 1 gene, copy number 11: OR11J6P.
- chr16:33,533,816–33,570,935, 4 genes, copy number 7: AC136944.1, AC136944.2, AC136944.4, AC136944.3.
- chr21:8,603,547–8,603,984, 1 gene, copy number 7: RPSAP68.
- chr21:13,038,160–13,120,807, 4 genes, copy number 6–11: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr21:43,092,956–43,107,570, 1 gene, copy number 7: U2AF1.
- chr21:43,115,334–43,141,092, 2 genes, copy number 7–10: MRPL51P2, FRGCA.

Autosomal genes at a single copy (total copy number 1): 217. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
